Somatic mutation profile of tumor specimen C3L-00447-03 (aliquot CPT0006910009) from CPTAC case C3L-00447, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 35.1 years (12,822 days).
Specimen C3L-00447-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1391ad85-5a65-4542-b6d2-7e56abc179b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00447-31 (Blood Derived Normal), aliquot CPT0002760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2e0f1da-83f1-4b5a-90f5-1b6cd6271339

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 3, Nonsense Mutation 3, 3'UTR 1, 3'Flank 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 371/705 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397516444, CM951291, CM951292, COSV56546524, COSV56553028, COSV56557871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPNE7 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 137/396 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.156); catalogued as rs764118471, COSV99254901; called by muse, mutect2, varscan2
- HMG20A | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776151929, COSV100287599, COSV60311492; called by muse, mutect2, varscan2
- ITPRIPL2 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67347324, COSV67347766; called by muse, mutect2
- MFSD3 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs1341476589; called by muse, mutect2, varscan2
- SUN5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs929302638; called by muse, mutect2, varscan2
- ABCB6 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 193/359 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACBD3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF5 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 173/479 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CFAP47 | c.2239C>A p.H747N | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); called by muse, mutect2
- DAOA | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 194/615 reads (32%) | called by muse, mutect2, varscan2
- DGKB | c.1926_1927insT p.E643* | Frame Shift Ins (INS) | VAF 46/160 reads (29%) | called by mutect2, pindel, varscan2
- DPH1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 90/268 reads (34%) | called by muse, mutect2, varscan2
- DUSP22 | c.263+2_263+16del p.X88_splice | Splice Site (DEL) | VAF 82/622 reads (13%) | called by mutect2, pindel
- FSTL4 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 339/1010 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRAMD1A | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C2 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 186/605 reads (31%) | called by muse, mutect2, varscan2
- MEDAG | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 142/403 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NSD3 | c.3870G>T p.S1290= | Splice Region (SNP) | VAF 70/173 reads (40%) | called by muse, varscan2
- PLSCR3 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 44/913 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2
- RNPEPL1 | c.1319T>A p.F440Y | Missense Mutation (SNP) | VAF 162/281 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TAS2R19 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 207/692 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- VPS13C | c.2884A>G p.I962V (on ENST00000644861 / NM_020821.3; = p.I919V on NM_017684.5) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.047); called by muse, mutect2
- ZBTB6 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF189 | c.1221A>C p.K407N | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1QTNF4 | c.69G>A p.P23= | Silent (SNP) | VAF 116/317 reads (37%) | catalogued as rs754704315, COSV56782761; called by muse, mutect2, varscan2
- DNAJC25 | c.540A>G p.T180= | Silent (SNP) | VAF 60/171 reads (35%) | catalogued as rs776791144; called by muse, mutect2, varscan2
- IFIT3 | c.333A>T p.S111= | Silent (SNP) | VAF 80/242 reads (33%) | called by muse, mutect2, varscan2
- LGI1 | c.969T>C p.D323= | Silent (SNP) | VAF 68/187 reads (36%) | called by muse, mutect2, varscan2
- LMTK2 | c.1341C>T p.L447= | Silent (SNP) | VAF 133/376 reads (35%) | catalogued as rs375715976; called by muse, mutect2, varscan2
- PTPRK | c.1395C>G p.L465= | Silent (SNP) | VAF 195/503 reads (39%) | catalogued as rs1294583233; called by muse, mutect2, varscan2
- SLC41A3 | c.957C>T p.T319= | Silent (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- SPON1 | c.1602C>T p.D534= | Silent (SNP) | VAF 22/598 reads (4%) | catalogued as rs782801059; called by muse, mutect2
- TP53I11 | c.444T>A p.T148= | Silent (SNP) | VAF 215/527 reads (41%) | called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764644 C>T | 3'Flank (SNP) | VAF 52/146 reads (36%) | called by muse, varscan2
- DNAI4 | c.1097-539C>T | Intron (SNP) | VAF 124/357 reads (35%) | called by muse, mutect2, varscan2
- EIF4A1 | c.515-147C>T | Intron (SNP) | VAF 65/218 reads (30%) | catalogued as rs1275963423; called by muse, mutect2, varscan2
- SLC22A8 | c.885+79C>T | Intron (SNP) | VAF 85/247 reads (34%) | called by muse, mutect2, varscan2
- XIRP2 | c.*656A>T | 3'UTR (SNP) | VAF 158/461 reads (34%) | called by muse, mutect2, varscan2
